Somatic mutation profile of tumor specimen TCGA-19-2631-01A (aliquot TCGA-19-2631-01A-01D-1353-08) from TCGA case TCGA-19-2631, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.5 years (27,200 days).
Specimen TCGA-19-2631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aa467a6-b21c-4722-8fd7-5f926a5ab20a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2631-10B (Blood Derived Normal), aliquot TCGA-19-2631-10B-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80d1a4e0-d6be-4289-b174-76e56bcb1950

The open-access MAF lists 81 somatic variants for this specimen: 67 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 29/750 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2
- ACCSL | c.1180del p.S394Vfs*25 | Frame Shift Del (DEL) | VAF 75/189 reads (40%) | catalogued as COSV66581931; called by mutect2, pindel, varscan2
- ADAM2 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55862898; called by muse, mutect2, varscan2
- AGFG2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs780962444, COSV53544298; called by muse, mutect2
- ANKRD26 | c.2698-2A>G p.X900_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | catalogued as rs757747401, COSV65775798; called by muse, mutect2, varscan2
- ANKRD34B | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58613948; called by muse, mutect2, varscan2
- ARMH4 | c.2252G>C p.R751T | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104388186, COSV50765093; called by muse, mutect2, varscan2
- ASB17 | c.680A>T p.K227M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV52411162; called by muse, mutect2, varscan2
- ATG4B | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.137); catalogued as COSV60351221; called by muse, mutect2, varscan2
- B3GNT3 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.327); catalogued as COSV59437855; called by muse, mutect2, varscan2
- BEND6 | c.810C>G p.S270R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV66069109; called by muse, mutect2, varscan2
- BMP5 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1399302813, COSV63703525; called by muse, mutect2, varscan2
- CEP70 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as COSV53875814; called by muse, mutect2, varscan2
- CHRND | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51320085; called by muse, mutect2, varscan2
- CREB3L1 | c.1303T>C p.W435R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as COSV55831514; called by muse, mutect2, varscan2
- DMD | c.6152G>A p.R2051Q | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756696562, COSV63758358; called by muse, mutect2, varscan2
- DPM1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs767978019, COSV54866536, COSV54867415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM53C | c.994A>G p.M332V | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.11); catalogued as rs759996540, COSV53511722; called by muse, mutect2, varscan2
- FGG | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs750162680, COSV60195478; called by muse, mutect2, varscan2
- FLT4 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs368426530, COSV56109911; called by muse, mutect2, varscan2
- FOXD4L5 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.199); catalogued as rs1190776212; called by mutect2, varscan2
- GLYR1 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV58927294; called by muse, mutect2, varscan2
- GPR85 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs748949997, COSV51783717; called by muse, mutect2, varscan2
- HTR2C | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs376838998, COSV52209513; called by muse, mutect2, varscan2
- IFI16 | c.1475C>A p.P492Q | Missense Mutation (SNP) | VAF 94/310 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV55534718; called by muse, mutect2, varscan2
- ITGA1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs764123493, COSV50883352; called by muse, mutect2, varscan2
- ITGAX | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201384441, COSV51646062, COSV51648324; called by muse, mutect2, varscan2
- KCNH6 | c.431T>C p.L144S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.387); catalogued as COSV59003935; called by muse, mutect2, varscan2
- LHFPL1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767818059, COSV64332935; called by muse, mutect2, varscan2
- LLGL1 | c.1214C>G p.P405R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV57498366; called by muse, mutect2, varscan2
- LRBA | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63956422; called by muse, mutect2
- LZTR1 | c.1310G>A p.W437* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as rs746949078, COSV53148642; called by muse, mutect2, varscan2
- MAP3K7 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65224637; called by muse, mutect2
- MED13L | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV56121013; called by muse, mutect2, varscan2
- MRC1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 117/172 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58889400; called by muse, mutect2, varscan2
- MTMR1 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64892480; called by muse, mutect2, varscan2
- NKAPL | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV59198063, COSV59199518; called by muse, mutect2, varscan2
- NRK | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV54597871; called by muse, mutect2, varscan2
- OR14A16 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV62926716; called by muse, mutect2, varscan2
- OR5A1 | c.455A>T p.Y152F | Missense Mutation (SNP) | VAF 255/641 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV57375717, COSV57376870; called by muse, mutect2, varscan2
- OR6C68 | c.101T>A p.M34K | Missense Mutation (SNP) | VAF 154/346 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV65563343; called by muse, mutect2, varscan2
- PCDHA1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 90/171 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV65374644; called by muse, mutect2, varscan2
- PKHD1 | c.6919G>A p.G2307S | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV61878103; called by muse, mutect2, varscan2
- PSTPIP2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs371604789; called by muse, mutect2, varscan2
- RAG1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs763843831, COSV55023805; called by muse, mutect2, varscan2
- RANBP6 | c.3106A>C p.I1036L | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52389654; called by muse, mutect2, varscan2
- RBM3 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV63202405, COSV63202567; called by muse, varscan2
- RBM48 | c.730_731del p.L244Afs*28 | Frame Shift Del (DEL) | VAF 52/207 reads (25%) | catalogued as rs770281416; called by mutect2, pindel, varscan2
- ROBO1 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.241); catalogued as COSV71394859, COSV71397226; called by muse, mutect2, varscan2
- SCN9A | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV57611587; called by muse, mutect2, varscan2
- SEC23B | c.1204A>G p.M402V | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV52720800; called by muse, mutect2, varscan2
- SLCO4C1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as rs373841324, COSV60516258; called by muse, mutect2, varscan2
- SPEF2 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as rs774221694, COSV56797280; called by muse, mutect2, varscan2
- SRC | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62440010; called by muse, mutect2, varscan2
- SRP54 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV53740061; called by muse, mutect2, varscan2
- SRRT | c.2482C>G p.P828A | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as COSV53818001; called by muse, mutect2, varscan2
- SYMPK | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55612193; called by muse, mutect2, varscan2
- TAF15 | c.577G>T p.D193Y (on ENST00000605844 / NM_139215.3; = p.D190Y on NM_003487.4) | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as CM162942; called by muse, varscan2
- TAFA2 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 50/114 reads (44%) | catalogued as COSV101352965, COSV101353930, COSV69178548; called by muse, mutect2, varscan2
- TLL2 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs61743696, COSV63570758; called by muse, mutect2, varscan2
- TMPRSS15 | c.2753T>A p.V918D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53040765; called by muse, mutect2, varscan2
- TRAPPC8 | c.499del p.S167Hfs*33 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as COSV51974440; called by mutect2, pindel, varscan2
- TTC6 | c.628G>A p.G210R (on ENST00000267368; = p.G1576R on NM_001310135.3) | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs572020102, COSV57447328, COSV57449892; called by muse, mutect2, varscan2
- ZBED1 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58134335; called by muse, varscan2
- ZDBF2 | c.7010G>A p.R2337H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs767560772, COSV65626629; called by muse, mutect2, varscan2
- ZSWIM2 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV54575910; called by muse, mutect2, varscan2
- THOC1 | c.761_763del p.K254del | In Frame Del (DEL) | VAF 40/118 reads (34%) | called by pindel, varscan2
- ANXA2R | c.84G>A p.V28= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV59214887; called by muse, mutect2, varscan2
- CABP4 | c.687G>A p.A229= | Silent (SNP) | VAF 71/167 reads (43%) | catalogued as rs774788112, COSV57796947, COSV57798692; called by muse, mutect2, varscan2
- CCKBR | c.771C>T p.S257= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs1046394124, COSV58101906; called by muse, mutect2, varscan2
- FLNB | c.6852C>T p.S2284= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs113304692; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPIN3 | c.2046G>T p.G682= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV60036563; called by muse, mutect2, varscan2
- MAGEC3 | c.1479T>C p.Y493= | Silent (SNP) | VAF 233/420 reads (55%) | catalogued as COSV53581023; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1263C>T p.N421= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs1565946077, COSV56620313; called by muse, mutect2, varscan2
- MUC16 | c.40890C>T p.A13630= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV66692533; called by muse, varscan2
- NFATC2 | c.2775G>A p.T925= | Silent (SNP) | VAF 56/245 reads (23%) | catalogued as rs148642400; called by muse, mutect2, varscan2
- NUTM2F | c.2016C>A p.P672= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53557857; called by mutect2, varscan2
- TGM1 | c.444T>C p.H148= | Silent (SNP) | VAF 95/215 reads (44%) | catalogued as COSV52863369; called by muse, mutect2, varscan2
- TLE1 | c.2004C>T p.T668= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs2229270; called by muse, mutect2, varscan2
- UMOD | c.924G>A p.S308= | Silent (SNP) | VAF 97/271 reads (36%) | catalogued as COSV56774592; called by muse, mutect2, varscan2
- ANK1 | c.5395-1270C>T | Intron (SNP) | VAF 23/52 reads (44%) | catalogued as rs760468292, COSV55887454; called by muse, mutect2, varscan2
